TCGA case TCGA-DX-A2J4 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f75d2589-fd7b-49a1-a1c8-0b4726b81f3c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Dedifferentiated liposarcoma: ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 60.6 years (22,131 days); Year of diagnosis: 2008; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 15; Tumor length measurement: 22; Tumor width measurement: 21.
   Pathology details: Consistent pathology review: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 18; Tumor width measurement: 17.

Follow-up (3 entries)
- Days to follow up: 1,666 days (4.6 years); Disease response: Tumor Free.
- Days to follow up: 2,408 days (6.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,309.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A2J4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 440 mg.
  Slide TCGA-DX-A2J4-01A-03-TSC: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A2J4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Intraabdominal.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,408 days; disease-specific survival: no event (censored), 2,408 days; disease-free interval: no event (censored), 2,408 days; progression-free interval: no event (censored), 2,408 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A2J4-01A-32D-A21P-01): tumor purity 0.35, ploidy 2.04, whole-genome doublings 0.
